Somatic mutation profile of tumor specimen ALCH-B2U2-TTP1-A (aliquot ALCH-B2U2-TTP1-A-1-0-D-A77K-36) from ALCHEMIST case ALCH-B2U2, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 52.8 years (19,287 days).
Specimen ALCH-B2U2-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 201b76ba-d20e-4233-9663-5597c9eed43e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2U2-NB1-A (Blood Derived Normal), aliquot ALCH-B2U2-NB1-A-1-0-D-A77K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/08889810-8250-4b19-a616-ddc7c6c23580

The open-access MAF lists 28 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 4, Frame Shift Del 2, Splice Site 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HEPH | c.3422G>A p.R1141H (on ENST00000343002; = p.R874H on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/422 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); catalogued as rs746393868, COSV100294680, COSV57959332; called by muse, mutect2
- JPH2 | c.1246C>T p.R416C | Missense Mutation (SNP) | VAF 41/558 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs794729025; ClinVar: uncertain significance; called by muse, mutect2
- ST6GAL2 | c.677A>G p.K226R | Missense Mutation (SNP) | VAF 23/124 reads (19%) | PolyPhen benign (0.005); catalogued as COSV64530672; called by muse, mutect2, varscan2
- TRIM58 | c.1156C>A p.L386M | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV63570863; called by muse, mutect2
- UNC13A | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.053); catalogued as rs529698632, COSV53197563; called by muse, varscan2
- ADCY7 | c.2926G>C p.D976H | Missense Mutation (SNP) | VAF 43/238 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ALMS1 | c.11251A>C p.T3751P | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ASAP3 | c.187C>T p.H63Y | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- CNOT2 | c.13G>C p.D5H | Missense Mutation (SNP) | VAF 125/592 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- COL3A1 | c.744del p.G249Vfs*14 | Frame Shift Del (DEL) | VAF 77/445 reads (17%) | called by mutect2, pindel, varscan2
- CRYBG2 | c.4038+1G>C p.X1346_splice | Splice Site (SNP) | VAF 22/127 reads (17%) | called by muse, varscan2
- DCST1 | c.1195T>C p.Y399H | Missense Mutation (SNP) | VAF 32/200 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FLNC | c.4799T>C p.V1600A | Missense Mutation (SNP) | VAF 82/260 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FOXD4L5 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 40/350 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by mutect2, varscan2
- HEXB | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); called by muse, mutect2
- MUC16 | c.4913G>T p.S1638I | Missense Mutation (SNP) | VAF 33/351 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.455); called by muse, mutect2
- N4BP2L1 | c.333A>G p.I111M | Missense Mutation (SNP) | VAF 42/253 reads (17%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- NFATC2IP | c.1168T>A p.S390T | Missense Mutation (SNP) | VAF 47/355 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- POP1 | c.3026C>T p.P1009L | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- SETD2 | c.1844del p.P615Qfs*7 | Frame Shift Del (DEL) | VAF 21/170 reads (12%) | called by mutect2, pindel, varscan2
- UTP3 | c.400A>C p.K134Q | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.062); called by muse, mutect2
- WDR35 | c.2938C>G p.Q980E (on ENST00000345530 / NM_001006657.2; = p.Q969E on NM_020779.4) | Missense Mutation (SNP) | VAF 29/324 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2
- CEP72 | c.1404G>T p.A468= | Silent (SNP) | VAF 54/206 reads (26%) | called by muse, varscan2
- FASTK | c.984G>A p.L328= | Silent (SNP) | VAF 52/212 reads (25%) | called by muse, mutect2, varscan2
- FILIP1 | c.522G>A p.K174= | Silent (SNP) | VAF 58/451 reads (13%) | called by muse, mutect2, varscan2
- QSER1 | c.1632T>C p.S544= (on ENST00000399302; = p.S673= on NM_001076786.3) | Silent (SNP) | VAF 9/56 reads (16%) | called by muse, mutect2, varscan2
- LAG3 | c.1431+57G>T | Intron (SNP) | VAF 16/110 reads (15%) | called by muse, mutect2, varscan2
- PHF8 | c.*1098G>A | 3'UTR (SNP) | VAF 14/146 reads (10%) | called by muse, mutect2, varscan2
